Somatic mutation profile of tumor specimen ALCH-AEBV-TTP1-A (aliquot ALCH-AEBV-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEBV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.9 years (22,258 days).
Specimen ALCH-AEBV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c581f131-8013-48aa-b0b7-0263c64afcdd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEBV-NB1-A (Blood Derived Normal), aliquot ALCH-AEBV-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8c84bdd-7e36-4695-bc70-7d571b7d80c5

The open-access MAF lists 1,005 somatic variants for this specimen: 704 protein-altering or splice-affecting, 188 silent, 113 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 615, Silent 188, Intron 50, Nonsense Mutation 47, 3'UTR 17, Splice Site 16, RNA 16, 5'UTR 11, 5'Flank 11, Splice Region 9, 3'Flank 8, Frame Shift Del 8.

Variants (750 of 1,005; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1112A>C p.Y371S | Missense Mutation (SNP) | VAF 112/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs387906666, CM099545, COSV50633987, COSV50637098; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RPS7 | c.76-1G>T p.X26_splice | Splice Site (SNP) | VAF 31/725 reads (4%) | catalogued as rs1057519624; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.535C>A p.H179N | Missense Mutation (SNP) | VAF 104/491 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs553471103; called by muse, mutect2, varscan2
- ABT1 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs782100852; called by muse, mutect2
- ACRV1 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 41/593 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV59755339; called by muse, mutect2
- ADAMTS12 | c.4093T>A p.C1365S | Missense Mutation (SNP) | VAF 15/416 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61264804; called by muse, mutect2
- ADAMTSL3 | c.2586G>T p.M862I | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1410008448; called by muse, mutect2
- ADD3 | c.1095G>T p.K365N | Missense Mutation (SNP) | VAF 22/265 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV53326752; called by muse, mutect2
- ADGRF4 | c.1992G>T p.R664S | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs766212816; called by muse, mutect2
- ADGRL2 | c.4366G>C p.V1456L (on ENST00000370717 / NM_001366005.1; = p.V1400L on NM_012302.4) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV54682278; called by muse, mutect2, varscan2
- AGT | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 105/851 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64185355; called by muse, mutect2, varscan2
- AKAP6 | c.3763A>T p.S1255C | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV99801301; called by muse, mutect2
- AMER1 | c.1459C>G p.L487V | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100365113; called by muse, mutect2
- AMER1 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.202); catalogued as COSV57667443; called by muse, mutect2
- ANKRD26 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 52/397 reads (13%) | catalogued as COSV65775975; called by muse, mutect2, varscan2
- ANKRD26 | c.2526G>T p.M842I | Missense Mutation (SNP) | VAF 52/400 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101063012; called by muse, mutect2, varscan2
- ANKRD30A | c.3742G>T p.V1248L (on ENST00000611781; = p.V1192L on NM_052997.2) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1160982123; called by muse, mutect2, varscan2
- ANO2 | c.2479C>A p.R827S (on ENST00000356134 / NM_001278597.3; = p.R831S on NM_001278596.3) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1001453035; called by muse, mutect2
- AQP9 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as rs1452564766; called by muse, mutect2
- ARHGEF11 | c.3154G>T p.G1052C | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100169019; called by muse, mutect2, varscan2
- ARHGEF6 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 35/833 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51696386; called by muse, mutect2
- ATRN | c.1577A>G p.N526S | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.241); catalogued as rs1387235131; called by muse, mutect2, varscan2
- AXDND1 | c.638+1G>A p.X213_splice | Splice Site (SNP) | VAF 22/184 reads (12%) | catalogued as rs768390176; called by muse, mutect2, varscan2
- BMP6 | c.1138C>A p.R380S | Missense Mutation (SNP) | VAF 100/906 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV51674413; called by muse, mutect2, varscan2
- BMPR1B | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs141032424; called by muse, mutect2, varscan2
- C11orf58 | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV57178124; called by muse, mutect2, varscan2
- CD1E | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 110/617 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1409078381, COSV100937077; called by muse, mutect2, varscan2
- CDH13 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 74/378 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.067); catalogued as rs377383586, COSV99221541; called by muse, mutect2, varscan2
- CDH22 | c.1625C>A p.A542D | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.444); catalogued as rs1314691615, COSV64840086; called by muse, mutect2
- CELA3A | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51585326; called by muse, mutect2, varscan2
- CEP70 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1164349607, COSV53874110; called by muse, mutect2, varscan2
- CFAP47 | c.2677G>T p.G893* | Nonsense Mutation (SNP) | VAF 21/443 reads (5%) | catalogued as rs1376066532, COSV99935026, COSV99935879; called by muse, mutect2
- CFHR2 | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs558414740; called by muse, mutect2
- CHD4 | c.1273G>T p.G425W (on ENST00000357008 / NM_001363606.2; = p.G438W on NM_001273.5) | Missense Mutation (SNP) | VAF 29/439 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1315086872; called by muse, mutect2
- CHRM1 | c.851C>A p.S284Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV61007068; called by muse, mutect2, varscan2
- CHRM2 | c.1036G>T p.V346L | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1455067791, COSV57774807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB3 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs557808043; called by muse, mutect2
- CHST2 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58884940; called by muse, mutect2
- CIB3 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs767528190, COSV54165469, COSV99521974; called by muse, mutect2, varscan2
- CLCA2 | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1207544288; called by muse, varscan2
- CLCA4 | c.1757C>A p.A586E | Missense Mutation (SNP) | VAF 82/731 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761274896; called by muse, mutect2, varscan2
- CNGA4 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 34/404 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs1353756952, COSV66006345; called by muse, mutect2
- CNTNAP2 | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 21/349 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62208504; called by muse, mutect2
- CSF2RA | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 159/794 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as COSV100817646; called by muse, mutect2, varscan2
- DCAF12L1 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 93/459 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.726); catalogued as COSV64422998; called by muse, mutect2, varscan2
- DCAF8L2 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 112/498 reads (22%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.701); catalogued as COSV70550352; called by muse, mutect2, varscan2
- DDAH2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1394257673, COSV65383867; called by muse, mutect2
- DDX53 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 36/290 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100029158; called by muse, mutect2, varscan2
- DDX56 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.914); catalogued as rs1272550057; called by muse, mutect2, varscan2
- DGKZ | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 57/254 reads (22%) | catalogued as rs764401862; called by muse, mutect2, varscan2
- DLG2 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54622090; called by muse, mutect2, varscan2
- DLGAP2 | c.130C>A p.Q44K | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated, low confidence (0.38); PolyPhen probably damaging (0.918); catalogued as rs1247768880; called by muse, mutect2, varscan2
- DMD | c.7576C>A p.Q2526K | Missense Mutation (SNP) | VAF 57/882 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as CM098444; called by muse, mutect2
- DMD | c.2176G>T p.V726F | Missense Mutation (SNP) | VAF 65/329 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); catalogued as rs886044365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMRT2 | c.1292C>A p.P431Q | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764593509, COSV99425974; called by muse, mutect2, varscan2
- DNAH11 | c.10180G>T p.G3394C | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs777202241; called by muse, mutect2, varscan2
- DNAJB2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV60675808; called by muse, mutect2, varscan2
- DNMT1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.348); catalogued as rs1257821053; called by muse, mutect2, varscan2
- DYNC2H1 | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99043768; called by muse, mutect2, varscan2
- EDIL3 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV56903908, COSV99677515; called by muse, varscan2
- EPHB1 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 17/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67670506; called by muse, mutect2
- EPS8L2 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201129457; called by muse, mutect2
- EZHIP | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as COSV100539432; called by muse, mutect2
- FAM83B | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV60922464; called by muse, mutect2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 30/222 reads (14%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FBN3 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs1221418974; called by muse, mutect2
- FER | c.199G>T p.V67L | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.996); catalogued as COSV99813856; called by muse, mutect2
- FFAR2 | c.904A>T p.R302* | Nonsense Mutation (SNP) | VAF 93/527 reads (18%) | catalogued as COSV55832954; called by muse, mutect2, varscan2
- FLG | c.955A>G p.R319G | Missense Mutation (SNP) | VAF 52/1102 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.152); catalogued as COSV64249239; called by muse, mutect2
- FNDC11 | c.347C>G p.T116R | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs146009691; called by muse, mutect2, varscan2
- FOLR1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 60/646 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56616634, COSV56617250; called by muse, mutect2
- FOXF2 | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 27/645 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99453116; called by muse, mutect2
- FSTL5 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.713); catalogued as rs748092347; called by muse, mutect2, varscan2
- GAK | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs780415271, COSV58506045; called by muse, mutect2, varscan2
- GCGR | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 53/339 reads (16%) | catalogued as rs936989263; called by muse, mutect2, varscan2
- GEMIN4 | c.2332T>C p.F778L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.716); catalogued as rs770985482; called by muse, mutect2, varscan2
- GLRA2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 34/332 reads (10%) | catalogued as COSV54348027; called by muse, mutect2
- GNAL | c.436G>T p.V146L (on ENST00000269162 / NM_001142339.3; = p.V223L on NM_182978.4) | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as CM140838; called by muse, mutect2
- GNB1 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV66100148; called by muse, mutect2
- GPR149 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs747593917; called by muse, mutect2
- GPR35 | c.763C>A p.R255S | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV60577448; called by muse, mutect2, varscan2
- GRIK2 | c.1317+1G>T p.X439_splice | Splice Site (SNP) | VAF 15/156 reads (10%) | catalogued as rs1002691544; called by muse, mutect2, varscan2
- GRM7 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 56/604 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63139420; called by muse, mutect2
- GRXCR1 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 64/467 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101295635; called by muse, mutect2, varscan2
- HAUS5 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV52547167; called by muse, mutect2, varscan2
- HCN1 | c.2537C>A p.S846* | Nonsense Mutation (SNP) | VAF 58/391 reads (15%) | catalogued as COSV100301983, COSV57520811; called by muse, mutect2, varscan2
- HERC2 | c.6231G>T p.L2077F | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs540717296; called by muse, varscan2
- HS3ST4 | c.1087G>C p.D363H | Missense Mutation (SNP) | VAF 76/577 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58805977; called by muse, mutect2, varscan2
- IFT140 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 125/482 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886051769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV5-51 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 117/632 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs577591701; called by muse, varscan2
- IGKV3-15 | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 196/2166 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs369139179; called by muse, mutect2
- IL22RA1 | c.44-1G>T p.X15_splice | Splice Site (SNP) | VAF 45/230 reads (20%) | catalogued as COSV54628927; called by muse, mutect2, varscan2
- IL2RA | c.99C>A p.H33Q | Missense Mutation (SNP) | VAF 28/624 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.148); catalogued as COSV56919648; called by muse, mutect2
- IZUMO1R | c.682C>A p.L228M (on ENST00000440961; = p.L235M on NM_001199206.3) | Missense Mutation (SNP) | VAF 89/379 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.053); catalogued as COSV100126862; called by muse, mutect2, varscan2
- JAKMIP3 | c.1681G>T p.G561W | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100059536; called by muse, mutect2, varscan2
- KIAA1755 | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV54073743; called by muse, mutect2
- KLHL1 | c.1975G>T p.A659S | Missense Mutation (SNP) | VAF 50/265 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV64777716; called by muse, mutect2, varscan2
- KRT6A | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 157/1148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58105408; called by muse, mutect2, varscan2
- KRTAP19-1 | c.54C>A p.F18L | Missense Mutation (SNP) | VAF 60/504 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.86); catalogued as COSV66861013; called by muse, mutect2, varscan2
- KRTAP9-7 | c.455C>A p.T152N | Missense Mutation (SNP) | VAF 66/361 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs1466804552; called by muse, mutect2, varscan2
- LAMA1 | c.5743G>T p.E1915* | Nonsense Mutation (SNP) | VAF 38/1104 reads (3%) | catalogued as COSV67536073; called by muse, mutect2
- LMX1A | c.940C>A p.Q314K | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54220059; called by muse, mutect2
- LPCAT1 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs375427371, COSV52036392; called by muse, mutect2
- LPL | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 88/619 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.897); catalogued as rs538543355; called by muse, mutect2, varscan2
- LRP4 | c.2348G>T p.R783L | Missense Mutation (SNP) | VAF 80/830 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101066795; called by muse, mutect2
- LRRC7 | c.2188C>A p.P730T (on ENST00000651989 / NM_001370785.2; = p.P697T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV50437690; called by muse, mutect2, varscan2
- MAP3K15 | c.3464C>A p.A1155E | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.171); catalogued as COSV58826934; called by muse, mutect2
- MARCHF11 | c.757C>A p.L253M | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60128655, COSV60131962; called by muse, mutect2, varscan2
- MATK | c.182G>A p.R61H (on ENST00000310132 / NM_139355.3; = p.R62H on NM_002378.4) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs762544633; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MGAM | c.4619-1G>T p.X1540_splice | Splice Site (SNP) | VAF 44/696 reads (6%) | catalogued as COSV101527399; called by muse, mutect2
- MIB2 | c.2054C>A p.S685Y | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV61543457; called by muse, mutect2, varscan2
- MIIP | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1441772009; called by muse, mutect2
- MLNR | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.666); catalogued as rs774435857, COSV54532363; called by muse, mutect2, varscan2
- MYH13 | c.957G>T p.E319D | Missense Mutation (SNP) | VAF 35/375 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV99352074; called by muse, mutect2
- NALCN | c.2488C>A p.H830N | Missense Mutation (SNP) | VAF 73/560 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475371083; called by muse, mutect2, varscan2
- NALCN | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.76); catalogued as rs752215175, COSV51914992; called by muse, mutect2, varscan2
- NARS2 | c.252-1G>C p.X84_splice | Splice Site (SNP) | VAF 28/153 reads (18%) | catalogued as COSV55256009; called by muse, mutect2, varscan2
- NAV3 | c.2299G>T p.G767C | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57080436; called by muse, mutect2
- NF1 | c.3964G>T p.D1322Y | Missense Mutation (SNP) | VAF 82/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62213397; called by mutect2, varscan2
- NLRP7 | c.2443C>T p.R815C (on ENST00000340844 / NM_206828.3; = p.R787C on NM_139176.3) | Missense Mutation (SNP) | VAF 55/470 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs768718588, COSV60175308; called by muse, mutect2, varscan2
- NLRP7 | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.292); catalogued as rs529348651, COSV60182791; called by muse, mutect2
- NLRX1 | c.1887del p.L630Ffs*10 | Frame Shift Del (DEL) | VAF 13/101 reads (13%) | catalogued as rs749769992; called by mutect2, pindel, varscan2
- NOS1 | c.2947C>G p.P983A | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.316); catalogued as rs1320700177; called by muse, mutect2
- NOS1AP | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs981522456; called by muse, mutect2
- NOX3 | c.1005G>C p.W335C | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50151690; called by muse, mutect2, varscan2
- NSMAF | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232951; called by muse, mutect2
- NUP133 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs750639556; called by muse, mutect2, varscan2
- NUP155 | c.2314C>G p.L772V (on ENST00000231498 / NM_153485.3; = p.L713V on NM_004298.4) | Missense Mutation (SNP) | VAF 91/567 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1169857158; called by muse, mutect2, varscan2
- OR10H2 | c.293C>A p.A98D | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100008874, COSV59945428; called by muse, mutect2, varscan2
- OR13C8 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100623054; called by muse, mutect2, varscan2
- OR13G1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as COSV62944166; called by muse, mutect2, varscan2
- OR1A2 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 45/173 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101126377; called by muse, mutect2, varscan2
- OR2B3 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.645); catalogued as COSV65850721; called by muse, mutect2
- OR2L8 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV100594080; called by muse, mutect2
- OR2T3 | c.937A>T p.R313* | Nonsense Mutation (SNP) | VAF 32/1080 reads (3%) | catalogued as COSV62083057, COSV62083737; called by muse, mutect2
- OR5H2 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.075); catalogued as rs1242556940; called by muse, mutect2, varscan2
- OR6C2 | c.649T>G p.L217V | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV59515470; called by muse, mutect2
- OR9G1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773527677, COSV56450428; called by muse, mutect2
- OTOF | c.3613C>T p.R1205C (on ENST00000272371 / NM_194248.3; = p.R458C on NM_004802.4) | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs747452208, COSV55499991, COSV99717869; called by muse, mutect2, varscan2
- P2RY10 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50681042; called by muse, mutect2, varscan2
- PANK4 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs372681543; called by muse, mutect2, varscan2
- PAPPA | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.776); catalogued as COSV60281605; called by muse, mutect2
- PCDH15 | c.4412C>A p.S1471* | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | catalogued as COSV57316551; called by muse, mutect2
- PCDHA6 | c.1478C>A p.S493* | Nonsense Mutation (SNP) | VAF 87/1276 reads (7%) | catalogued as rs532373432; called by muse, mutect2
- PCDHA9 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.983); catalogued as rs781993576; called by muse, mutect2
- PCDHB6 | c.1871C>A p.T624N | Missense Mutation (SNP) | VAF 66/932 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs782447100, COSV99170077; called by muse, mutect2
- PCDHB7 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as COSV50753556; called by muse, mutect2
- PCGF1 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs760532339, COSV52044153; called by muse, mutect2, varscan2
- PCNX1 | c.1359G>T p.K453N | Missense Mutation (SNP) | VAF 26/501 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV99455716; called by muse, mutect2
- PDZRN4 | c.1380T>A p.D460E (on ENST00000402685 / NM_001164595.2; = p.D202E on NM_013377.4) | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.497); catalogued as rs1429268147; called by muse, mutect2, varscan2
- PHACTR1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 32/565 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV60672684; called by muse, mutect2
- PHEX | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 50/776 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.832); catalogued as COSV101039291; called by muse, mutect2
- PHF20 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 53/444 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59184541, COSV59188529; called by muse, mutect2, varscan2
- PLCD3 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1173932005; called by muse, mutect2, varscan2
- PLPPR5 | c.515G>T p.S172I | Missense Mutation (SNP) | VAF 69/800 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV99587610; called by muse, mutect2
- PMS2 | c.1239A>T p.K413N | Missense Mutation (SNP) | VAF 328/999 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as CD040607; called by mutect2, varscan2
- POM121L12 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs753136724; called by muse, mutect2, varscan2
- POU3F1 | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.116); catalogued as COSV65948411; called by muse, mutect2, varscan2
- PRKD2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.674); catalogued as COSV99354127; called by muse, mutect2
- PRODH2 | c.409G>T p.A137S (on ENST00000301175; = p.A61S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs770675022, COSV99995312; called by muse, varscan2
- PROS1 | c.1828G>A p.A610T | Missense Mutation (SNP) | VAF 125/423 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.166); catalogued as COSV101260736; called by muse, mutect2, varscan2
- PRPSAP2 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); catalogued as rs1335279295; called by muse, mutect2, varscan2
- PRR23B | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as rs1484398986; called by muse, mutect2, varscan2
- PSMG3 | c.106G>T p.V36L | Missense Mutation (SNP) | VAF 53/337 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV52920480; called by muse, mutect2, varscan2
- PTPRC | c.3796G>A p.G1266S | Missense Mutation (SNP) | VAF 40/834 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV100722185; called by muse, mutect2
- PTPRC | c.3797G>T p.G1266V | Missense Mutation (SNP) | VAF 40/828 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV61406477; called by muse, mutect2
- PUM1 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 205/951 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV57085412; called by muse, mutect2, varscan2
- RAD54B | c.389G>T p.W130L | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368351289; called by muse, mutect2, varscan2
- REG3A | c.374G>A p.S125N | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV59408670; called by muse, mutect2, varscan2
- RHAG | c.1172C>A p.P391Q | Missense Mutation (SNP) | VAF 58/823 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV57703276; called by muse, mutect2
- ROBO3 | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs765662222; called by muse, mutect2, varscan2
- RPH3A | c.823G>T p.A275S (on ENST00000389385 / NM_001143854.2; = p.A271S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/320 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.255); catalogued as COSV66992503; called by muse, mutect2
- RTN4RL1 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58676811; called by muse, mutect2
- RXFP3 | c.1221C>G p.I407M | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV57504408, COSV57508152; called by muse, mutect2
- RYR1 | c.4618C>T p.Q1540* | Nonsense Mutation (SNP) | VAF 95/634 reads (15%) | catalogued as COSV62110754; called by muse, mutect2, varscan2
- RYR2 | c.10517G>T p.R3506L | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100769225, COSV63670201; called by mutect2, varscan2
- RYR3 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211942; called by muse, mutect2, varscan2
- SALL1 | c.3431C>T p.S1144F | Missense Mutation (SNP) | VAF 59/456 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV51759852; called by muse, mutect2, varscan2
- SCN11A | c.3990G>T p.K1330N | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100182390; called by muse, mutect2
- SHANK1 | c.6458G>T p.R2153L | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53248109; called by muse, mutect2, varscan2
- SHOX | c.669C>A p.H223Q | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.263); catalogued as rs1472432567; called by muse, mutect2, varscan2
- SIGLEC7 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV58315614, COSV99978809; called by muse, mutect2, varscan2
- SLC12A7 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs769009597, COSV53754161; called by muse, mutect2, varscan2
- SLC12A8 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV100102327; called by muse, mutect2
- SLC18A1 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52346812; called by muse, mutect2, varscan2
- SLC5A10 | c.1309G>T p.G437W (on ENST00000395645 / NM_001042450.4; = p.G453W on NM_152351.5) | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99408172; called by muse, mutect2, varscan2
- SLC5A12 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV101237764; called by muse, mutect2, varscan2
- SLFN14 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs919139903; called by muse, mutect2
- SNTG1 | c.832T>A p.F278I | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV52445741, COSV52474615; called by muse, mutect2
- SOS1 | c.1132A>T p.T378S | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.045); catalogued as COSV67673689; called by muse, mutect2, varscan2
- SPANXN4 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | catalogued as COSV65141261; called by muse, mutect2
- SPOCK3 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693169, COSV62738586; called by muse, mutect2
- TACC1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 132/591 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs201280385; called by muse, mutect2, varscan2
- TBX21 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51598212; called by muse, mutect2
- TBX3 | c.2213C>T p.S738F (on ENST00000257566 / NM_016569.4; = p.S718F on NM_005996.4) | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs1389276999; called by muse, mutect2, varscan2
- TCF7L2 | c.1457G>T p.C486F (on ENST00000355995 / NM_001367943.1; = p.C463F on NM_030756.5) | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53340274; called by muse, mutect2
- TECRL | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs778546497; called by muse, mutect2, varscan2
- TIAM2 | c.925G>C p.G309R | Missense Mutation (SNP) | VAF 62/427 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100019707; called by muse, mutect2, varscan2
- TKTL2 | c.1147C>A p.R383S | Missense Mutation (SNP) | VAF 165/1005 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99761410; called by muse, mutect2, varscan2
- TLL1 | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 68/661 reads (10%) | catalogued as rs1046165531; called by muse, mutect2, varscan2
- TLR5 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 114/1174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778639819; called by muse, mutect2
- TMEM117 | c.1222G>C p.G408R | Missense Mutation (SNP) | VAF 15/344 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861723; called by muse, mutect2
- TMEM131 | c.5540G>T p.S1847I | Missense Mutation (SNP) | VAF 19/376 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.136); catalogued as COSV51780487; called by muse, mutect2
- TMEM255A | c.258G>T p.R86S | Missense Mutation (SNP) | VAF 40/327 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59028637; called by muse, mutect2, varscan2
- TMEM74 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1003845245; called by muse, mutect2, varscan2
- TMTC2 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs758445375; called by muse, mutect2, varscan2
- TNIP1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as COSV100161043; called by muse, mutect2
- TOMM20 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 66/634 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV64013499; called by muse, mutect2
- TRAPPC4 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.674); catalogued as rs782305914; called by muse, mutect2
- TRIM58 | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 35/413 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.006); catalogued as COSV63569464; called by muse, mutect2
- U2AF2 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58272683; called by muse, mutect2, varscan2
- USO1 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs567240121; called by muse, mutect2, varscan2
- USP29 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54145418, COSV54146838; called by muse, mutect2
- WDR11 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 60/534 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs756514742, COSV54785031, COSV99676892; called by muse, mutect2, varscan2
- WNK3 | c.3010G>T p.V1004L | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100671153; called by muse, mutect2, varscan2
- YME1L1 | c.2258A>G p.Y753C (on ENST00000326799 / NM_139312.3; = p.Y696C on NM_014263.4) | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569136741, COSV100463675; called by muse, mutect2
- ZAN | c.1688C>G p.P563R | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs1323175986, COSV100769594; called by muse, mutect2, varscan2
- ZFHX4 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 50/358 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); catalogued as COSV50632102, COSV51494233; called by muse, mutect2, varscan2
- ZIC3 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 56/418 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as COSV54972441; called by muse, mutect2, varscan2
- ZIK1 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 33/316 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV56737507; called by muse, mutect2, varscan2
- ZNF114 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV59944488; called by muse, mutect2, varscan2
- ZNF256 | c.867C>A p.H289Q | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV56597530; called by muse, mutect2
- ZNF536 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100835835; called by muse, mutect2, varscan2
- ZRANB3 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99923005; called by muse, mutect2
- ZSCAN10 | c.383G>T p.R128L (on ENST00000252463; = p.R183L on NM_032805.3) | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs149971053; called by muse, mutect2, varscan2
- A1BG | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ABCA13 | c.6316del p.E2106Kfs*8 | Frame Shift Del (DEL) | VAF 82/422 reads (19%) | called by mutect2, pindel, varscan2
- ABL1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 131/779 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP2 | c.1410G>T p.L470F | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB1 | c.1850A>T p.N617I (on ENST00000360697 / NM_001346687.2; = p.N577I on NM_001112.4) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- ADCY9 | c.3314A>T p.E1105V | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY9 | c.3313G>T p.E1105* | Nonsense Mutation (SNP) | VAF 46/345 reads (13%) | called by muse, mutect2, varscan2
- ADGRA2 | c.1187dup p.T397Hfs*8 | Frame Shift Ins (INS) | VAF 134/489 reads (27%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.2857G>T p.A953S (on ENST00000379869 / NM_001079858.3; = p.A950S on NM_005756.4) | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- ADGRG2 | c.883C>A p.P295T (on ENST00000379869 / NM_001079858.3; = p.P292T on NM_005756.4) | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.103); called by muse, mutect2
- ADGRG4 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 16/373 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- ADGRG4 | c.3812C>G p.T1271S | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- ADNP2 | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- ADPRH | c.153G>C p.W51C | Missense Mutation (SNP) | VAF 54/477 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFM | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 52/443 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- AGAP1 | c.1051-1G>T p.X351_splice | Splice Site (SNP) | VAF 65/390 reads (17%) | called by muse, mutect2, varscan2
- AGTR1 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.029); called by muse, mutect2
- AHNAK2 | c.7728G>T p.M2576I | Missense Mutation (SNP) | VAF 88/482 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- ALAS2 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 32/497 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2
- AMER1 | c.3365C>A p.T1122N | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- AMOT | c.2491G>A p.D831N (on ENST00000371959 / NM_001113490.1; = p.D422N on NM_133265.3) | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2
- AMPD1 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 36/834 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.063); called by muse, mutect2
- ANK1 | c.2238C>A p.H746Q | Missense Mutation (SNP) | VAF 220/817 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ANK2 | c.1735del p.A579Qfs*66 | Frame Shift Del (DEL) | VAF 115/813 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD30B | c.3345C>A p.D1115E | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.204); called by muse, mutect2
- ANKRD36 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, varscan2
- APBA1 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- AQR | c.2786G>A p.C929Y | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARAP3 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ARHGAP17 | c.1725-5C>G | Splice Region (SNP) | VAF 126/935 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP4 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP42 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- ARL14EPL | c.344G>C p.C115S | Missense Mutation (SNP) | VAF 42/848 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARSH | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.2); called by muse, mutect2
- ASAP1 | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ASH1L | c.1508A>C p.Q503P | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ATG7 | c.188T>G p.L63* | Nonsense Mutation (SNP) | VAF 17/375 reads (5%) | called by muse, mutect2
- ATRX | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2
- B4GALNT4 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- BANK1 | c.20G>C p.G7A | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- BBOX1 | c.654C>A p.H218Q | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCL9 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 22/428 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BCORL1 | c.1967C>A p.A656D | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCORL1 | c.2281G>T p.G761C | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2
- BICC1 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- BICDL1 | c.1130A>G p.Y377C | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- BNC2 | c.2580G>C p.M860I | Missense Mutation (SNP) | VAF 118/747 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BOD1L1 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 53/567 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); called by muse, mutect2
- BPTF | c.6637G>C p.G2213R | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- BRCA1 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- BRINP2 | c.2309T>C p.L770P | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- BSX | c.597G>T p.E199D | Missense Mutation (SNP) | VAF 70/283 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BTBD11 | c.3055G>T p.A1019S (on ENST00000280758 / NM_001018072.2; = p.A556S on NM_001017523.2) | Missense Mutation (SNP) | VAF 55/460 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- BTBD7 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 83/490 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C16orf78 | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 138/358 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.28); called by muse, varscan2
- CACNA1B | c.5839G>A p.A1947T | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CAD | c.2322G>T p.E774D | Missense Mutation (SNP) | VAF 17/512 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CALHM3 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAMTA1 | c.2172C>A p.N724K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); called by mutect2, varscan2
- CAPN11 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASK | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBL | c.2525A>C p.Q842P | Missense Mutation (SNP) | VAF 56/590 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- CCDC15 | c.2429_2430del p.E810Afs*17 | Frame Shift Del (DEL) | VAF 36/170 reads (21%) | called by pindel, varscan2
- CCDC168 | c.18337G>A p.G6113R | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CCDC168 | c.7234T>A p.F2412I | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CCDC27 | c.1612G>T p.E538* | Nonsense Mutation (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- CCDC74A | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); called by muse, mutect2
- CCNB3 | c.976C>A p.L326I | Missense Mutation (SNP) | VAF 20/431 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.035); called by muse, mutect2
- CCR5 | c.853C>A p.L285I | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.9); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CD1B | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 32/434 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CD22 | c.2141G>T p.R714M | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CD5 | c.1268T>A p.M423K | Missense Mutation (SNP) | VAF 82/420 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CDC14C | c.1123A>T p.R375* (on ENST00000428251; = p.R268* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 93/880 reads (11%) | called by muse, mutect2, varscan2
- CDH10 | c.1735A>T p.T579S | Missense Mutation (SNP) | VAF 70/870 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); called by muse, mutect2
- CDK5R1 | c.203T>A p.V68E | Missense Mutation (SNP) | VAF 72/724 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.223); called by muse, mutect2
- CELSR1 | c.4442A>T p.Y1481F | Missense Mutation (SNP) | VAF 41/267 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- CENPI | c.1090G>T p.G364C | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CEP126 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CEP128 | c.961G>C p.G321R | Missense Mutation (SNP) | VAF 53/322 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CEP162 | c.3088G>C p.E1030Q | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP250 | c.761A>C p.Q254P | Missense Mutation (SNP) | VAF 57/496 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CEP250 | c.6038G>T p.R2013L | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.015); called by muse, mutect2
- CEP76 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, varscan2
- CFAP65 | c.2314C>A p.H772N | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CFH | c.3015G>C p.K1005N | Missense Mutation (SNP) | VAF 166/674 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD8 | c.4481A>T p.Y1494F (on ENST00000646647 / NM_001170629.2; = p.Y1215F on NM_020920.4) | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CHST2 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CKMT1A | c.918G>T p.W306C | Missense Mutation (SNP) | VAF 37/290 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CLEC1A | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- CNTN5 | c.168C>A p.S56R | Missense Mutation (SNP) | VAF 162/1274 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNTNAP3 | c.1874C>A p.T625K | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- CNTNAP4 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- COL11A1 | c.1890T>A p.D630E | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL20A1 | c.1498T>A p.C500S | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- COL24A1 | c.3103G>A p.G1035S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CROCC2 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CSMD2 | c.5129G>T p.S1710I | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CSMD3 | c.7349C>A p.P2450Q (on ENST00000297405 / NM_001363185.1; = p.P2346Q on NM_052900.3) | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSNK2A1 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTLA4 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 150/798 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CUBN | c.4750G>T p.E1584* | Nonsense Mutation (SNP) | VAF 107/803 reads (13%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 109/535 reads (20%) | called by muse, mutect2, varscan2
- DCAF13 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCSTAMP | c.1204A>G p.I402V | Missense Mutation (SNP) | VAF 22/538 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.047); called by muse, mutect2
- DDR2 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 177/953 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DEFB125 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- DENND2D | c.471C>G p.I157M | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- DENND4C | c.1990-2A>T p.X664_splice | Splice Site (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2
- DHTKD1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DHX36 | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DKK3 | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2
- DLGAP3 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 72/430 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLL3 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DMP1 | c.564G>T p.E188D | Missense Mutation (SNP) | VAF 98/498 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- DNAH6 | c.3466A>C p.T1156P | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- DNAH6 | c.7477G>T p.A2493S | Missense Mutation (SNP) | VAF 168/658 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- DNAH9 | c.6580A>T p.I2194F | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DNAH9 | c.8594C>A p.A2865D | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAH9 | c.9743C>A p.P3248H | Missense Mutation (SNP) | VAF 49/541 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DNAJC1 | c.1026G>T p.M342I | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2
- DSC3 | c.2194T>A p.L732I | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DUS2 | c.728G>C p.R243P | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EBLN1 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.15); called by muse, varscan2
- ECHS1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.072); called by muse, mutect2
- ECSCR | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- EHBP1 | c.2531C>T p.T844I | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); called by muse, mutect2
- EHD3 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ELP1 | c.3964A>G p.R1322G | Missense Mutation (SNP) | VAF 61/916 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ENO4 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ENTHD1 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- EP400 | c.7538A>T p.Q2513L | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.283); called by muse, varscan2
- ERCC2 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 72/622 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC6L2 | c.3470A>T p.N1157I | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERN1 | c.1321C>G p.L441V | Missense Mutation (SNP) | VAF 63/564 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ERVV-2 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ESRRB | c.1148A>T p.H383L | Missense Mutation (SNP) | VAF 56/782 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.038); called by muse, mutect2
- EVX1 | c.427+2T>A p.X143_splice | Splice Site (SNP) | VAF 18/77 reads (23%) | called by muse, varscan2
- EXOC1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- EZH2 | c.1279C>T p.P427S (on ENST00000460911 / NM_001203247.2; = p.P432S on NM_004456.5) | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAAP20 | c.281T>A p.L94Q | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- FAM124B | c.1270A>G p.R424G | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAM171A1 | c.2029G>T p.A677S | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.026); called by muse, mutect2
- FAM184B | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- FAM47A | c.815dup p.L273Afs*9 | Frame Shift Ins (INS) | VAF 89/469 reads (19%) | called by mutect2, pindel, varscan2
- FAM71E2 | c.1878C>A p.S626R | Missense Mutation (SNP) | VAF 74/327 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FANCB | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.173); called by muse, mutect2
- FAT3 | c.1084G>T p.V362F | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2
- FBN2 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXL19 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- FBXO21 | c.945G>T p.L315F | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCAMR | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 21/311 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2
- FCN3 | c.188-8G>A | Splice Region (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- FH | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 72/601 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.5669-1G>T p.X1890_splice | Splice Site (SNP) | VAF 12/369 reads (3%) | called by muse, mutect2
- FOXB2 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, varscan2
- FOXC2 | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD1 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCB | c.1516G>T p.A506S | Missense Mutation (SNP) | VAF 87/648 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- FSCB | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 43/381 reads (11%) | called by muse, mutect2, varscan2
- FSIP2 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0.03); called by muse, mutect2
- FTMT | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- GABRB3 | c.604G>T p.G202* | Nonsense Mutation (SNP) | VAF 152/1027 reads (15%) | called by muse, mutect2, varscan2
- GAP43 | c.134A>T p.H45L | Missense Mutation (SNP) | VAF 32/601 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GART | c.2894G>T p.R965M | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- GATAD2A | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- GCM2 | c.739C>A p.L247I | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2
- GGH | c.948A>G p.I316M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.022); called by muse, mutect2
- GIMD1 | c.353del p.F118Sfs*6 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- GIPC1 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- GK | c.1394C>G p.A465G (on ENST00000427190 / NM_001205019.2; = p.A459G on NM_000167.6) | Missense Mutation (SNP) | VAF 82/1306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- GLRA2 | c.1217C>A p.A406D | Missense Mutation (SNP) | VAF 160/760 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLUD2 | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 40/751 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.07); called by muse, mutect2
- GNAS | c.1652G>T p.W551L | Missense Mutation (SNP) | VAF 55/908 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); called by muse, mutect2
- GPR148 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GPR153 | c.831G>T p.W277C | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR45 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 74/204 reads (36%) | called by muse, mutect2, varscan2
- GREM2 | c.431T>A p.F144Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.034); called by muse, varscan2
- GRID2 | c.1524G>T p.L508F | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- GRIK1 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 64/609 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.01); called by muse, mutect2
- GRM1 | c.1038G>C p.E346D | Missense Mutation (SNP) | VAF 90/816 reads (11%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- GRM1 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 90/815 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GRPR | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 32/576 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- GYG2 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAO2 | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- HEATR1 | c.5999A>T p.Y2000F | Missense Mutation (SNP) | VAF 106/542 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HERC2 | c.13061A>C p.H4354P | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HLA-DQB2 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 35/398 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2
- HMCN2 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOXB7 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by mutect2, varscan2
- HRNR | c.454A>T p.T152S | Missense Mutation (SNP) | VAF 29/1134 reads (3%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- HTATSF1 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 53/479 reads (11%) | called by muse, mutect2, varscan2
- HTR7 | c.465T>A p.C155* | Nonsense Mutation (SNP) | VAF 28/249 reads (11%) | called by muse, varscan2
- HUWE1 | c.10834G>C p.D3612H | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2
- HYDIN | c.11598G>T p.Q3866H | Missense Mutation (SNP) | VAF 108/445 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IFIT2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFT140 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- IGHG3 | c.113C>A p.T38K | Missense Mutation (SNP) | VAF 76/627 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- IGHM | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- IGHV3-43 | c.217del p.D73Mfs*11 | Frame Shift Del (DEL) | VAF 103/486 reads (21%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 48/752 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL10RA | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- IL16 | c.1753T>A p.F585I | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- IL1RAPL1 | c.2075C>A p.S692Y | Missense Mutation (SNP) | VAF 233/929 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ILDR2 | c.433T>C p.C145R | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- IQCK | c.803-2A>T p.X268_splice | Splice Site (SNP) | VAF 83/291 reads (29%) | called by muse, mutect2, varscan2
- IRAK4 | c.1318A>G p.K440E | Missense Mutation (SNP) | VAF 30/507 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2
- IRF8 | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 37/812 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2
- IRS2 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, mutect2
- ITGAL | c.3395C>A p.P1132Q | Missense Mutation (SNP) | VAF 94/400 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITIH1 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 103/885 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- KCNC2 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNJ11 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK18 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 31/453 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- KCNQ2 | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 33/345 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2
- KCP | c.2971C>T p.R991C (on ENST00000620378; = p.R1051C on NM_001366122.1) | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- KDM5A | c.2735C>T p.S912L | Missense Mutation (SNP) | VAF 50/726 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- KIAA0232 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 67/353 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KIAA0319 | c.1807G>T p.D603Y | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF13A | c.2377G>C p.A793P | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF20A | c.746G>C p.S249T | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2
- KIF4B | c.2387G>T p.R796L | Missense Mutation (SNP) | VAF 44/552 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2
- KIF4B | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 62/718 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2
- KIR3DX1 | n.1181A>T | Splice Region (SNP) | VAF 80/568 reads (14%) | called by muse, mutect2, varscan2
- KLF5 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- KLHL31 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 51/620 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KRT24 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.056); called by muse, mutect2
- KRT6C | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 54/776 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- KRTAP9-1 | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 96/845 reads (11%) | SIFT tolerated (0.37); called by muse, mutect2, varscan2
- KRTAP9-6 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 88/410 reads (21%) | SIFT tolerated (0.09); called by muse, varscan2
- L1CAM | c.1823T>A p.V608E | Missense Mutation (SNP) | VAF 97/455 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB3 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 35/1034 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- LAX1 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 116/516 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LCA5 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LHFPL1 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 125/545 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LIMS2 | c.317A>T p.D106V (on ENST00000355119 / NM_001161403.3; = p.D130V on NM_017980.4) | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.309); called by muse, mutect2
- LINGO2 | c.1634C>A p.T545K | Missense Mutation (SNP) | VAF 91/473 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRIT1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- LRIT3 | c.1982G>T p.S661I | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- LRP12 | c.1939T>G p.L647V | Missense Mutation (SNP) | VAF 24/729 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.202); called by muse, mutect2
- LRP1B | c.10624G>C p.D3542H | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC14B | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- LRRC3B | c.67C>A p.L23I | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.219); called by muse, mutect2
- LRRC4B | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.106); called by muse, mutect2
- LTC4S | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 23/309 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGEB3 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 16/446 reads (4%) | called by muse, mutect2
- MAGEB5 | c.611G>A p.W204* | Nonsense Mutation (SNP) | VAF 66/599 reads (11%) | called by muse, mutect2, varscan2
- MAGEB6B | c.823A>C p.S275R | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.32); called by muse, mutect2
- MAP1B | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2
- MAP4K1 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP7D3 | c.2516C>A p.T839K | Missense Mutation (SNP) | VAF 32/830 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.235); called by muse, mutect2
- MBTPS2 | c.224G>C p.W75S | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCC | c.986G>A p.R329K | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); called by muse, mutect2
- MCMDC2 | c.1930T>C p.Y644H | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- MECOM | c.544C>T p.H182Y (on ENST00000468789 / NM_001105078.4; = p.H370Y on NM_004991.4) | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MEIS3 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MKS1 | c.1558A>T p.S520C | Missense Mutation (SNP) | VAF 165/937 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MMEL1 | c.505A>G p.R169G | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MMP2 | c.1370C>A p.P457H | Missense Mutation (SNP) | VAF 117/902 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- MMUT | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 71/535 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MPL | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 18/390 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- MTRR | c.1589C>T p.P530L (on ENST00000264668; = p.P503L on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MUC19 | c.1092C>G p.S364R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.514); called by muse, mutect2
- MYO1D | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 24/863 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); called by muse, mutect2
- MYO9A | c.6958G>A p.D2320N | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- MYSM1 | c.751A>G p.N251D | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- MYT1L | c.2538G>C p.Q846H | Missense Mutation (SNP) | VAF 145/550 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYT1L | c.975C>G p.S325R | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NAALADL2 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- NASP | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NBPF12 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 125/907 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NCKAP5 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.181); called by muse, mutect2
- NCOA2 | c.3481C>A p.Q1161K | Missense Mutation (SNP) | VAF 107/1009 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- NCOA6 | c.6101A>G p.H2034R | Missense Mutation (SNP) | VAF 40/352 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NEB | c.6643A>T p.K2215* | Nonsense Mutation (SNP) | VAF 58/589 reads (10%) | called by muse, mutect2
- NEK10 | c.2798G>T p.S933I | Missense Mutation (SNP) | VAF 55/374 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NELL2 | c.1488T>A p.N496K | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIBAN3 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.069); called by muse, mutect2
- NIN | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- NIPAL1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2
- NLRP11 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRX1 | c.1415A>G p.D472G | Missense Mutation (SNP) | VAF 91/388 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NME5 | c.491A>G p.H164R | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- NMS | c.187A>T p.N63Y | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- NOP9 | c.245G>C p.R82P | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NRK | c.377G>T p.W126L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUDCD3 | c.1004G>T p.W335L | Missense Mutation (SNP) | VAF 74/569 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT3 | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 53/508 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP153 | c.1759A>G p.K587E | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2
- NUTM1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); called by muse, mutect2
- NWD2 | c.2689C>G p.R897G | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- OMG | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.23); called by muse, mutect2
- OPHN1 | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 26/363 reads (7%) | called by muse, mutect2
- OR10S1 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 181/782 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- OR10V1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 115/496 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR1C1 | c.721T>A p.C241S | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2AT4 | c.74C>A p.P25Q | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2T10 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR2T27 | c.620T>A p.L207H | Missense Mutation (SNP) | VAF 50/1466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OR4C13 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR51A7 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR51G1 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 144/598 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- OR5D18 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR5M11 | c.227A>T p.N76I | Missense Mutation (SNP) | VAF 119/595 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- OR5W2 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OTC | c.801C>A p.S267R | Missense Mutation (SNP) | VAF 176/990 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOF | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OTUD5 | c.1291A>G p.S431G | Missense Mutation (SNP) | VAF 25/408 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- OTUD6A | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PADI3 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 34/552 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- PAFAH1B1 | c.671+8A>T | Splice Region (SNP) | VAF 19/605 reads (3%) | called by muse, mutect2
- PAN3 | c.2049+7A>T | Splice Region (SNP) | VAF 16/155 reads (10%) | called by muse, mutect2, varscan2
- PAPPA2 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 38/396 reads (10%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- PARP9 | c.2249A>T p.K750M | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PAX3 | c.553A>C p.K185Q | Missense Mutation (SNP) | VAF 39/366 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCDH15 | c.5767G>T p.V1923L | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH15 | c.2922C>A p.Y974* | Nonsense Mutation (SNP) | VAF 13/301 reads (4%) | called by muse, mutect2
- PCDH19 | c.3415G>T p.G1139C (on ENST00000373034 / NM_001184880.2; = p.G1091C on NM_020766.3) | Missense Mutation (SNP) | VAF 57/645 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); called by muse, mutect2
- PCDHB15 | c.1946A>T p.E649V | Missense Mutation (SNP) | VAF 127/865 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PCDHGA4 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 35/345 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHGA8 | c.2227G>T p.V743F | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.379); called by muse, mutect2
- PCDHGB2 | c.2277A>T p.Q759H | Missense Mutation (SNP) | VAF 58/479 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDHA2 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 73/478 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PDILT | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 185/886 reads (21%) | called by muse, mutect2, varscan2
- PDPK1 | c.1527G>C p.K509N | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PDPR | c.443+8A>T | Splice Region (SNP) | VAF 34/381 reads (9%) | called by muse, mutect2, varscan2
- PDZRN4 | c.2622C>G p.S874R (on ENST00000402685 / NM_001164595.2; = p.S616R on NM_013377.4) | Missense Mutation (SNP) | VAF 39/521 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2
- PHF20 | c.874A>T p.K292* | Nonsense Mutation (SNP) | VAF 25/579 reads (4%) | called by muse, mutect2
- PHF20 | c.875A>T p.K292I | Missense Mutation (SNP) | VAF 23/584 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.219); called by muse, mutect2
- PHF20L1 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- PHF21A | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); called by muse, mutect2
- PHKB | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 114/1021 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PI15 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 17/483 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.171); called by muse, mutect2
- PIGV | c.907A>T p.I303L | Missense Mutation (SNP) | VAF 24/689 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- PIM2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKD2L1 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 22/453 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- PLD1 | c.1077A>T p.K359N | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PLEKHF1 | c.480_496del p.C161Lfs*19 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.1828A>T p.I610F | Missense Mutation (SNP) | VAF 21/616 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- POM121L2 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 66/478 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- POT1 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- POTEJ | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 58/370 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by mutect2, varscan2
- POU6F2 | c.1170C>A p.N390K | Missense Mutation (SNP) | VAF 42/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PPP4R3C | c.1487A>T p.D496V | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PPP4R3C | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PRAMEF20 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 48/1225 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PRELID3A | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- PREX2 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- PRIM2 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 33/206 reads (16%) | called by muse, mutect2, varscan2
- PRL | c.605G>C p.C202S | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRPF8 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 66/565 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- PRPH2 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 76/810 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRR5 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 31/154 reads (20%) | PolyPhen benign (0.03); called by muse, mutect2, varscan2
- PRR5 | c.27G>T p.R9S | Missense Mutation (SNP) | VAF 31/156 reads (20%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRUNE2 | c.8005G>T p.G2669C | Missense Mutation (SNP) | VAF 85/502 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PSG3 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PSMD14 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PTBP2 | c.229G>T p.E77* (on ENST00000426398 / NM_001300986.2; = p.E69* on NM_021190.4) | Nonsense Mutation (SNP) | VAF 26/202 reads (13%) | called by muse, varscan2
- PXDNL | c.728T>A p.V243E | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2
- RACGAP1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 36/517 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.419); called by muse, mutect2
- RAD50 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- RALGAPA1 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- RALGAPA2 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RBPJ | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 63/368 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCC1 | c.429G>T p.W143C | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- RELN | c.9797C>A p.P3266H | Missense Mutation (SNP) | VAF 36/954 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2
- RFNG | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 76/439 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- RIBC1 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- RIMS2 | c.1719A>T p.K573N (on ENST00000666250 / NM_001348490.2; = p.K381N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RIMS2 | c.3546A>T p.A1182= | Splice Region (SNP) | VAF 16/220 reads (7%) | called by muse, mutect2
- RIOK2 | c.1254G>C p.E418D | Missense Mutation (SNP) | VAF 46/450 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF113A | c.154A>C p.T52P | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RNF41 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, varscan2
- RORC | c.1153A>T p.M385L | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS16 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- RYR2 | c.12304C>A p.L4102M | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SALL4 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- SATL1 | c.916C>A p.Q306K (on ENST00000395409; = p.Q493K on NM_001012980.2) | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); called by muse, mutect2
- SCD5 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN10A | c.1173G>C p.L391F | Missense Mutation (SNP) | VAF 78/1249 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN4A | c.4406G>T p.R1469L | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2
- SEC23B | c.382_383insT p.P128Lfs*9 | Frame Shift Ins (INS) | VAF 104/702 reads (15%) | called by mutect2, pindel, varscan2
- SERPINA11 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 121/736 reads (16%) | called by muse, mutect2, varscan2
- SERPINI1 | c.1060G>T p.V354F | Missense Mutation (SNP) | VAF 73/483 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- SIN3A | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SIRPD | c.467G>A p.G156D | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SLC12A5 | c.1075A>T p.T359S (on ENST00000454036 / NM_001134771.2; = p.T336S on NM_020708.5) | Missense Mutation (SNP) | VAF 75/640 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC13A1 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, varscan2
- SLC17A6 | c.1748A>T p.*583Lext*3 | Nonstop Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- SLC17A7 | c.376G>T p.G126C | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A8 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLFN14 | c.1592G>T p.R531M | Missense Mutation (SNP) | VAF 67/417 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLIT1 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 18/455 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLITRK2 | c.1341G>C p.Q447H | Missense Mutation (SNP) | VAF 56/562 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLMAP | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- SMARCC2 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SNIP1 | c.472G>T p.G158W | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SORCS3 | c.3289C>A p.L1097M | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOWAHD | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.355); called by muse, mutect2
- SP6 | c.567dup p.K190* | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel
- SPAM1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, varscan2
- SPRR2F | c.218A>T p.*73Lext*9 | Nonstop Mutation (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- SPTB | c.1952G>A p.S651N | Missense Mutation (SNP) | VAF 54/1140 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by muse, mutect2
- SRSF2 | c.212C>G p.A71G | Missense Mutation (SNP) | VAF 101/653 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STARD8 | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- STX8 | c.344A>T p.E115V | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SUPT20HL2 | c.788G>C p.R263T | Missense Mutation (SNP) | VAF 34/602 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- SYTL4 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2
- TAAR5 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TAB3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- TAF1C | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TENM1 | c.3883G>T p.G1295* | Nonsense Mutation (SNP) | VAF 84/354 reads (24%) | called by muse, varscan2
- TENM3 | c.3779C>T p.T1260I | Missense Mutation (SNP) | VAF 55/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TENT4B | c.1075A>T p.K359* (on ENST00000561678 / NM_001365323.2; = p.K344* on NM_001040284.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/723 reads (4%) | called by muse, mutect2
- TEX13C | c.847G>T p.E283* | Nonsense Mutation (SNP) | VAF 48/406 reads (12%) | called by muse, mutect2, varscan2
- TEX15 | c.220C>A p.Q74K (on ENST00000256246; = p.Q457K on NM_001350162.2) | Missense Mutation (SNP) | VAF 68/379 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TFR2 | c.979A>T p.T327S | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TIE1 | c.2812G>C p.D938H | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLN2 | c.3310A>T p.M1104L | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.024); called by muse, mutect2
- TLR1 | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 32/274 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLR1 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM131 | c.5308G>T p.A1770S | Missense Mutation (SNP) | VAF 123/435 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMEM268 | c.233A>T p.Y78F | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMX1 | c.645G>T p.Q215H | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TNFRSF11B | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 29/798 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.084); called by muse, mutect2
- TNFSF10 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNN | c.3875T>G p.L1292R | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- TOX2 | c.662C>A p.S221* (on ENST00000358131 / NM_001098798.2; = p.S170* on NM_032883.3) | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- TP53BP1 | c.3119G>T p.C1040F | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TPSD1 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- TRAV1-1 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 37/660 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- TRDN | c.717A>C p.E239D | Missense Mutation (SNP) | VAF 22/642 reads (3%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); called by muse, mutect2
- TRIM3 | c.1825G>T p.V609F | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TRIT1 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- TTC3 | c.5035G>T p.A1679S | Missense Mutation (SNP) | VAF 31/308 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TTC6 | c.610C>G p.L204V (on ENST00000267368; = p.L1570V on NM_001310135.3) | Missense Mutation (SNP) | VAF 72/407 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.8800A>C p.K2934Q (on ENST00000591111; = p.K2888Q on NM_003319.4) | Missense Mutation (SNP) | VAF 35/819 reads (4%) | PolyPhen probably damaging (0.951); called by muse, mutect2
- TTN | c.4482C>A p.G1494= (on ENST00000591111; = p.G1448= on NM_003319.4) | Splice Region (SNP) | VAF 36/616 reads (6%) | called by muse, mutect2
- TUBB2B | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); called by muse, mutect2
- TWIST1 | c.483G>T p.Q161H | Missense Mutation (SNP) | VAF 24/686 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2
- UBR4 | c.3812G>T p.G1271V | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2
- UNC79 | c.4849G>T p.G1617W (on ENST00000393151 / NM_001346218.2; = p.G1440W on NM_020818.5) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UNC80 | c.1864C>T p.L622F | Missense Mutation (SNP) | VAF 72/626 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- USP29 | c.1664C>A p.A555E | Missense Mutation (SNP) | VAF 44/406 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- UTP14A | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- UTRN | c.9274G>T p.D3092Y | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VAV1 | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCAM1 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- VHL | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- VN1R2 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- VN1R2 | c.837G>T p.W279C | Missense Mutation (SNP) | VAF 58/499 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- VPS37B | c.367-1G>C p.X123_splice | Splice Site (SNP) | VAF 21/578 reads (4%) | called by muse, mutect2
- VPS45 | c.1730G>A p.G577E (on ENST00000644526; = p.E546K on NM_007259.5) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2
- VWA5B1 | c.1066A>T p.R356* | Nonsense Mutation (SNP) | VAF 23/129 reads (18%) | called by muse, mutect2, varscan2
- WBP2NL | c.169C>A p.R57= | Splice Region (SNP) | VAF 55/263 reads (21%) | called by muse, mutect2, varscan2
- WDR82 | c.395G>C p.R132P | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- XKR3 | c.105dup p.S36* | Frame Shift Ins (INS) | VAF 22/194 reads (11%) | called by mutect2, pindel, varscan2
- XYLT1 | c.1370+1G>T p.X457_splice | Splice Site (SNP) | VAF 101/407 reads (25%) | called by muse, mutect2, varscan2
- YLPM1 | c.5614G>T p.D1872Y | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB18 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 94/478 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZFP14 | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 51/255 reads (20%) | called by muse, mutect2, varscan2
- ZFP91 | c.908+1G>T p.X303_splice | Splice Site (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- ZFPM2 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 108/1057 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by mutect2, varscan2
- ZIM2 | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 75/480 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZMYM3 | c.2260C>A p.Q754K | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2
- ZNF135 | c.436C>A p.P146T (on ENST00000313434 / NM_001289401.2; = p.P158T on NM_003436.4) | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ZNF135 | c.437C>A p.P146Q (on ENST00000313434 / NM_001289401.2; = p.P158Q on NM_003436.4) | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF217 | c.2590C>T p.L864F | Missense Mutation (SNP) | VAF 41/676 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ZNF251 | c.1502G>T p.R501M | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZNF441 | c.195_214del p.X65_splice | Splice Site (DEL) | VAF 12/135 reads (9%) | called by mutect2, pindel
- ZNF568 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF616 | c.783G>T p.R261S | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ZNF619 | c.1128G>T p.R376S | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF69 | c.1348G>T p.G450W | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF691 | c.691G>A p.E231K (on ENST00000372502; = p.E200K on NM_015911.3) | Missense Mutation (SNP) | VAF 58/704 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); called by muse, mutect2
- ZNF700 | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF716 | c.465A>T p.K155N | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF790 | c.1411dup p.I471Nfs*5 | Frame Shift Ins (INS) | VAF 12/94 reads (13%) | called by mutect2, pindel, varscan2
- ACTN2 | c.1968G>A p.K656= | Silent (SNP) | VAF 29/998 reads (3%) | called by muse, mutect2
- ADAM19 | c.1923G>T p.G641= | Silent (SNP) | VAF 43/394 reads (11%) | catalogued as rs779487366; called by muse, mutect2, varscan2
- ADAM23 | c.351C>T p.L117= | Silent (SNP) | VAF 21/369 reads (6%) | catalogued as rs767707320; called by muse, mutect2
- ADAMTS2 | c.3015G>T p.A1005= | Silent (SNP) | VAF 34/476 reads (7%) | catalogued as rs1462683964; called by muse, mutect2
- ADGRF4 | c.15C>A p.S5= | Silent (SNP) | VAF 56/345 reads (16%) | catalogued as COSV51952755; called by muse, mutect2, varscan2
- AKAP17A | c.819G>T p.L273= | Silent (SNP) | VAF 26/501 reads (5%) | called by muse, mutect2
- ANKRD66 | c.261C>T p.L87= | Silent (SNP) | VAF 11/240 reads (5%) | called by muse, mutect2
- APCS | c.510G>A p.V170= | Silent (SNP) | VAF 117/493 reads (24%) | called by muse, mutect2, varscan2
- ARPP21 | c.1455C>T p.H485= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as rs755093191; called by muse, mutect2, varscan2
- ARSH | c.1446C>G p.L482= | Silent (SNP) | VAF 24/513 reads (5%) | called by muse, mutect2
- ASXL3 | c.4035C>A p.S1345= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- ATP13A1 | c.1227G>T p.G409= | Silent (SNP) | VAF 35/346 reads (10%) | called by muse, mutect2, varscan2
- ATRX | c.4581A>C p.S1527= | Silent (SNP) | VAF 28/560 reads (5%) | called by muse, mutect2
- BIVM-ERCC5 | c.3198G>A p.E1066= | Silent (SNP) | VAF 48/382 reads (13%) | catalogued as COSV63244296; called by muse, mutect2, varscan2
- BRCA2 | c.10146G>A p.L3382= | Silent (SNP) | VAF 48/518 reads (9%) | called by muse, mutect2
- BRWD3 | c.3636T>C p.Y1212= | Silent (SNP) | VAF 28/420 reads (7%) | called by muse, mutect2
- BSN | c.11028C>A p.R3676= | Silent (SNP) | VAF 25/340 reads (7%) | called by muse, mutect2
- BTBD18 | c.1155G>A p.Q385= | Silent (SNP) | VAF 28/372 reads (8%) | catalogued as rs1243585306; called by muse, mutect2
- BTBD3 | c.660G>A p.L220= | Silent (SNP) | VAF 28/668 reads (4%) | catalogued as COSV54778344; called by muse, mutect2
- C12orf71 | c.435G>T p.L145= | Silent (SNP) | VAF 15/406 reads (4%) | called by muse, mutect2
- C9 | c.210T>C p.F70= | Silent (SNP) | VAF 52/652 reads (8%) | catalogued as COSV54676370; called by muse, mutect2
- CABP2 | c.549C>A p.A183= | Silent (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- CACNA1E | c.5097C>A p.A1699= | Silent (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2, varscan2
- CACNA1F | c.5103G>A p.G1701= | Silent (SNP) | VAF 94/742 reads (13%) | called by muse, mutect2, varscan2
- CACNA1F | c.5016C>G p.R1672= | Silent (SNP) | VAF 42/684 reads (6%) | called by muse, mutect2
- CACNA1S | c.117C>A p.P39= | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as rs761494499; called by muse, mutect2, varscan2
- CARD6 | c.1773A>G p.E591= | Silent (SNP) | VAF 57/291 reads (20%) | called by muse, mutect2, varscan2
- CCDC78 | c.1248G>A p.L416= | Silent (SNP) | VAF 41/374 reads (11%) | catalogued as COSV53496098; called by muse, mutect2, varscan2
- CDK16 | c.87G>A p.E29= | Silent (SNP) | VAF 60/964 reads (6%) | called by muse, mutect2
- CEACAM6 | c.987C>T p.A329= | Silent (SNP) | VAF 10/247 reads (4%) | called by muse, mutect2
- CEP295NL | c.993C>T p.L331= | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- CHD5 | c.3657C>T p.I1219= | Silent (SNP) | VAF 76/424 reads (18%) | catalogued as rs761205850; called by muse, mutect2, varscan2
- CHST7 | c.1149C>G p.R383= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV52099631; called by muse, mutect2
- CLCN7 | c.1329G>T p.G443= | Silent (SNP) | VAF 40/331 reads (12%) | catalogued as rs1420074737, COSV51974661; called by muse, mutect2, varscan2
- COL6A3 | c.5496C>A p.A1832= | Silent (SNP) | VAF 75/754 reads (10%) | catalogued as COSV55090057; called by muse, mutect2
- COQ8B | c.1479A>T p.A493= | Silent (SNP) | VAF 48/343 reads (14%) | called by muse, mutect2, varscan2
- CPD | c.2559C>T p.T853= | Silent (SNP) | VAF 16/91 reads (18%) | called by muse, varscan2
- CROCC2 | c.459C>A p.A153= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- CSMD1 | c.5935C>T p.L1979= (on ENST00000520002; = p.L1978= on NM_033225.6) | Silent (SNP) | VAF 10/250 reads (4%) | catalogued as rs1197098846, COSV100154861; called by muse, mutect2
- CTTNBP2NL | c.699C>T p.A233= | Silent (SNP) | VAF 54/339 reads (16%) | called by muse, mutect2, varscan2
- CUBN | c.9156C>T p.A3052= | Silent (SNP) | VAF 56/902 reads (6%) | called by muse, mutect2
- CYB5R1 | c.282C>T p.V94= | Silent (SNP) | VAF 34/362 reads (9%) | called by muse, mutect2
- DACH2 | c.57G>T p.P19= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as rs773783988, COSV64172728; called by muse, mutect2
- DCAF4L2 | c.54A>T p.T18= | Silent (SNP) | VAF 50/358 reads (14%) | called by muse, mutect2, varscan2
- DDX17 | c.408G>T p.V136= | Silent (SNP) | VAF 40/460 reads (9%) | called by muse, mutect2
- DDX5 | c.1521C>T p.T507= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs782704842, COSV56750385; called by muse, mutect2, varscan2
255 further variants in this file (0 protein-altering or splice-affecting, 142 silent, 113 other) are not listed here.
